Gene-level copy-number profile of tumor specimen TCGA-V1-A9ZI-01A from TCGA case TCGA-V1-A9ZI, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9ZI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.d772f8ce-750a-409e-90e5-f2d536b36b62.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V1-A9ZI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/afd20e74-6cc6-4207-9bfd-dc0b45ff846a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 7,522; copy number 2: 47,461; copy number 3: 3,047; copy number 4: 125; copy number 5: 1; copy number 6: 208; copy number 7: 1,406.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V1-A9ZI-01A-11D-A41J-01): tumor purity 0.8, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:119,268,692–120,687,332, 13 genes (within-gene range 0–1): TNFAIP8, RN7SL174P, RNA5SP190, HSD17B4, AC010409.1, FABP5P6, FAM170A, TUBAP15, AC008550.1, AC008574.1, RNU6-718P, AC113418.1, PRR16.
- chr16:89,969,773–90,222,851, 14 genes: CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr18:52,340,197–53,535,903, 1 gene (within-gene range 0–1): DCC.
- chr18:53,237,101–53,629,990, 4 genes: MIR4528, LINC01917, LINC01919, RPL29P32.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,615 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:42,836,674–145,066,685, 1,569 genes, copy number 6–7 (broad region; genes not listed).
- chr16:46,469,341–48,167,238, 46 genes, copy number 5–7: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA, 5S_rRNA, PHKB, RNA5SP425, AC007599.2, AC007599.1, EIF4BP5, NDUFA5P11, LINC02133, AC141846.1, LINC02192, LINC02134, AC096996.3, AC096996.1, ABCC12, AC096996.2.

Autosomal genes at a single copy (total copy number 1): 5,136. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
